Somatic mutation profile of tumor specimen 0DDA7D from CCDI case PBBNJM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,722 days).
Specimen 0DDA7D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c6b18d-986f-4fa5-bf67-b7b9b97d1c7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDA71 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa01b2a2-6b78-498c-ac68-52f4dac4823c

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918459, CM013416, COSV61007856; ClinVar: pathogenic; called by muse, mutect2
- FASLG | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 40/823 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60680960; called by muse, mutect2
- GPX5 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 76/608 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs773612149, COSV101297251; called by muse, mutect2, varscan2
- GLOD5 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- KIAA1549 | c.4722G>T p.K1574N | Missense Mutation (SNP) | VAF 44/898 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
